MMRF case MMRF_1832 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e8cf0ba0-d90d-45df-ba6c-b90697c7b771

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.8 years (26,215 days); ISS stage: III; Days to last known disease status: 1,076 days (2.9 years); Days to last follow up: 1,076 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 210 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 211 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 1): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4160 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 15.6 µg/mL; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 356 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 5.94 mmol/L; C-Reactive Protein 1.17 mg/dL.
- Day 89 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 153 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 4.57 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 204 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 8.03 mmol/L.
- Day 183 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 140 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 7.2 g/dL; Glucose 8.14 mmol/L.
- Day 257 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 225 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 11.9 mmol/L.
- Day 369 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 5.47 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 197 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 8.64 mmol/L.
- Day 453 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 126 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 5.52 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 190 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 7.04 mmol/L.
- Day 537 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 4.57 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 7.59 mmol/L.
- Day 621: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 5.72 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 6.99 mmol/L.
- Day 705: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12550 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 1.98 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 6.38 mmol/L.
- Day 789: M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 119 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.82 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 201 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.2 mmol/L; Albumin 37.6 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 901: Serum Free Immunoglobulin Light Chain, Kappa 236 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 243 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 5.67 mmol/L.
- Day 985: Serum Free Immunoglobulin Light Chain, Kappa 277 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 6.14 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 6.44 mmol/L.
- Day 1,076: M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 350 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 218 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -8: Weight: 137 kg; Height: 186 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_1832_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1832_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
